CGCI case BLGSP-71-19-99997 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/5f82fd25-c6a3-44e5-a2ef-da446ff78344

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Samples BLGSP-71-19-99997-17A.1, BLGSP-71-19-99997-17A.2 (2 with the same recorded description): Sample type: Lymphoid Normal; Tissue type: Normal; Specimen type: Lymphoid; Preservation method: Frozen.
